MMRF case MMRF_2525 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/c5fb14ea-e06d-4871-9efe-b0c9cb48bad6

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 51 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 51.5 years (18,795 days); ISS stage: II; Days to last known disease status: 631 days (1.7 years); Days to last follow up: 631 days (1.7 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0 (ECOG 2): M Protein 3.42 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.577 mg/dL; Immunoglobulin G 40.3 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 1.8 µg/mL; Hemoglobin 5.7 mmol/L; Leukocytes 8.9 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 347 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.63 mmol/L; Albumin 27 g/L; Total Protein 10.9 g/dL; Glucose 4.84 mmol/L; C-Reactive Protein 2.8 mg/dL.
- Day 92 (ECOG 2): M Protein 3.97 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.786 mg/dL; Hemoglobin 5.27 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 0.77 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.33 mmol/L; Albumin 26 g/L; Total Protein 8.9 g/dL; Glucose 4.95 mmol/L.
- Day 183: M Protein 2.24 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.726 mg/dL; Hemoglobin 6.32 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 1.89 ×10⁹/L; Platelets 288 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.23 mmol/L; Albumin 34 g/L; Total Protein 7.3 g/dL; Glucose 3.74 mmol/L.
- Day 253 (ECOG 1): Hemoglobin 6.51 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.02 ×10⁹/L; Platelets 340 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 2.14 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 4.68 mmol/L.
- Day 358 (ECOG 1): M Protein 0.44 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.849 mg/dL; Immunoglobulin G 12.7 g/L; Immunoglobulin A 0.73 g/L; Immunoglobulin M 0.75 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 284 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.43 mmol/L; Albumin 48 g/L; Total Protein 8 g/dL; Glucose 3.36 mmol/L.
- Day 463 (ECOG 1): Lactate Dehydrogenase 3.57 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 1.81 ×10⁹/L; Platelets 289 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 7 g/dL; Glucose 4.79 mmol/L.
- Day 547 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.932 mg/dL; Hemoglobin 7.44 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.57 ×10⁹/L; Platelets 271 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 7.1 g/dL; Glucose 4.51 mmol/L.
- Day 631 (ECOG 1): Hemoglobin 7.69 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.17 ×10⁹/L; Platelets 238 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.43 mmol/L; Albumin 42 g/L; Total Protein 7.3 g/dL; Glucose 3.69 mmol/L.

Other clinical attributes
- Day 0: Weight: 57 kg; Height: 162 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling.

Biospecimens (2 samples)
- Sample MMRF_2525_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_2525_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
